Somatic mutation profile of tumor specimen TARGET-10-PARESP-09A (aliquot TARGET-10-PARESP-09A-01D) from TARGET case TARGET-10-PARESP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (600 days).
Specimen TARGET-10-PARESP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11a12927-643d-471b-9191-ef78eb53ac20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARESP-10A (Blood Derived Normal), aliquot TARGET-10-PARESP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7987a62-cd7d-4e41-b84b-4f940e48ca5a

The open-access MAF lists 81 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Intron 8, 5'UTR 5, 3'Flank 3, Nonsense Mutation 2, 3'UTR 2, 5'Flank 1, Nonstop Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNIPL | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs150851524; called by muse, mutect2, varscan2
- BTN3A1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs374921833, COSV50024493; called by muse, mutect2, varscan2
- CNTLN | c.3354G>C p.L1118F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs768978772; called by muse, mutect2, varscan2
- DCDC1 | c.2749C>T p.P917S (on ENST00000597505 / NM_001367979.1; = p.P24S on NM_020869.3) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV100337896; called by muse, mutect2, varscan2
- DMRT3 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1261539213, COSV51903809; called by muse, mutect2, varscan2
- DPY19L1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs767729568; called by muse, mutect2, varscan2
- GAR1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV56993156; called by muse, mutect2
- GRK4 | c.280G>A p.D94N (on ENST00000398052 / NM_182982.3; = p.D62N on NM_005307.3) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs377489222; called by muse, mutect2, varscan2
- MB21D2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1202524709; called by muse, mutect2, varscan2
- NEBL | c.1382G>C p.G461A | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV65802571; called by muse, mutect2, varscan2
- PRMT6 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV63655300; called by muse, mutect2, varscan2
- SYT8 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs772100955; called by muse, mutect2, varscan2
- ALMS1 | c.6641C>G p.S2214C | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.211); called by muse, mutect2
- BANK1 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- BTBD10 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- C3orf14 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DHX36 | c.3026G>C p.*1009Sext*36 | Nonstop Mutation (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- GEN1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HSP90AA1 | c.1839C>G p.I613M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- IGLV4-60 | c.353_362delinsTTT p.S118Ifs*? | Frame Shift Del (DEL) | VAF 33/46 reads (72%) | called by pindel, varscan2*
- INSYN2B | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LOXHD1 | c.4369C>G p.L1457V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LOXHD1 | c.4177C>A p.H1393N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- LRRC9 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- METTL2A | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MUC5B | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC5B | c.5143C>G p.P1715A | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCAN | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NT5DC1 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUP205 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
- OR10D3 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5M10 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- OR7C1 | c.483G>C p.L161F | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD8 | c.2388G>C p.L796F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PIGO | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIWIL4 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRQ | c.3797G>A p.R1266K (on ENST00000616559; = p.R1224K on NM_001145026.2) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF19B | c.1966A>G p.S656G | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SERPINH1 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TMPRSS3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- UBR4 | c.10561G>C p.E3521Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- UNC13C | c.4846C>G p.Q1616E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF416 | c.1278T>G p.I426M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ZNF880 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAZ2B | c.4653G>A p.T1551= | Silent (SNP) | VAF 77/164 reads (47%) | catalogued as rs777277917; called by muse, mutect2, varscan2
- BOD1L1 | c.261G>C p.L87= | Silent (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- CASR | c.1932C>G p.L644= (on ENST00000490131; = p.L721= on NM_000388.4) | Silent (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- CHIA | c.150C>G p.L50= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV58477857; called by muse, mutect2, varscan2
- CNTN5 | c.1272G>A p.L424= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99681045; called by muse, mutect2
- CYP2A6 | c.918C>G p.V306= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- FAM124B | c.1044C>G p.L348= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- FAT4 | c.5988G>A p.K1996= | Silent (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
- GBF1 | c.1939C>T p.L647= (on ENST00000369983 / NM_001377137.1; = p.L646= on NM_004193.3) | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- IGF2R | c.4008C>T p.G1336= | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- ITPR2 | c.4950C>T p.G1650= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs552541041, COSV67269386; called by muse, mutect2, varscan2
- NRK | c.2724A>T p.A908= | Silent (SNP) | VAF 79/88 reads (90%) | catalogued as COSV54608165; called by muse, mutect2, varscan2
- OR51F2 | c.684C>T p.L228= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV59064558, COSV59065065; called by muse, mutect2, varscan2
- OTP | c.312G>A p.Q104= | Silent (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- OTP | c.81G>A p.V27= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1317886605; called by muse, mutect2, varscan2
- RABL2B | c.42G>T p.G14= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- AC006971.1 | n.4332G>C | RNA (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- CEP120 | c.*63C>G | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- DOCK5 | c.2755-65G>A | Intron (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- EIF1B | c.-46G>A | 5'UTR (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- GIGYF2 | c.712+1207G>A | Intron (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- IFNGR2 | c.74-3378C>G | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- NOX4 | c.57+66G>A | Intron (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- OR10D3 | c.-45C>T | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- PARD6G | c.-34G>C | 5'UTR (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100783345; called by muse, mutect2, varscan2
- PCCB | chr3:136334461 G>C | 3'Flank (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- PCMT1 | c.*22C>T | 3'UTR (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- PHF14 | c.-100C>T | 5'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, varscan2
- PLEKHG3 | chr14:64749283 G>A | 3'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as rs753963756; called by muse, varscan2
- RN7SL211P | chr2:64905006 G>A | 3'Flank (SNP) | VAF 44/114 reads (39%) | catalogued as rs1035985402; called by muse, mutect2, varscan2
- SFTPA2 | c.-24+207C>T | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- SLC45A1 | chr1:8324329 G>A | 5'Flank (SNP) | VAF 16/36 reads (44%) | catalogued as rs988994344, COSV57098377; called by muse, mutect2, varscan2
- SNRPG | c.180+735G>C | Intron (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- TNNI1 | c.*2+162G>A | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.-115T>A | 5'UTR (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- WDR90 | c.1966+61G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
